Somatic mutation profile of tumor specimen TCGA-HD-A633-01A (aliquot TCGA-HD-A633-01A-11D-A28R-08) from TCGA case TCGA-HD-A633, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 74.1 years (27,057 days).
Specimen TCGA-HD-A633-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa47a8a1-81b8-4f16-ae46-c82f4b8a4b00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HD-A633-10A (Blood Derived Normal), aliquot TCGA-HD-A633-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64267535-d682-4808-8b8f-0001313f536b

The open-access MAF lists 154 somatic variants for this specimen: 115 protein-altering or splice-affecting, 36 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 36, Nonsense Mutation 7, Frame Shift Del 5, Frame Shift Ins 3, Splice Site 2, 3'UTR 2, Splice Region 2, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.3566G>A p.R1189Q | Missense Mutation (SNP) | VAF 43/117 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60788908, COSV60805381; called by muse, mutect2, varscan2
- ACTN3 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs773160523, COSV100074408; called by muse, mutect2, varscan2
- ADAM29 | c.160T>A p.Y54N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100822133; called by muse, mutect2, varscan2
- ADCY2 | c.1668G>T p.R556S | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.105); catalogued as COSV100603413; called by muse, mutect2, varscan2
- ADGRG4 | c.5926G>T p.E1976* | Nonsense Mutation (SNP) | VAF 42/59 reads (71%) | catalogued as COSV99796083; called by muse, mutect2, varscan2
- AGT | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100794438; called by muse, mutect2, varscan2
- AMPD1 | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV100815131; called by muse, mutect2, varscan2
- ATP13A5 | c.1771G>T p.A591S | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as COSV60869929; called by muse, mutect2, varscan2
- BAHCC1 | c.6193C>T p.P2065S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV100311880; called by muse, mutect2, varscan2
- BIN2 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 26/57 reads (46%) | catalogued as COSV99909543, COSV99909562; called by muse, mutect2, varscan2
- BLZF1 | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.024); catalogued as COSV100250618; called by muse, mutect2, varscan2
- BRINP1 | c.1714T>A p.S572T | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV56292579, COSV99776241; called by muse, mutect2, varscan2
- BTBD7 | c.2572G>T p.E858* | Nonsense Mutation (SNP) | VAF 19/60 reads (32%) | catalogued as COSV100598015, COSV58284980; called by muse, mutect2, varscan2
- C1RL | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99864820; called by muse, mutect2, varscan2
- CCDC174 | c.627G>C p.M209I | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100358636; called by muse, mutect2, varscan2
- CCDC39 | c.640C>G p.R214G | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs749794148, COSV56478360, COSV99869927; called by muse, mutect2, varscan2
- CCDC88C | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV101105950; called by muse, mutect2, varscan2
- CDC42EP4 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs185165304, COSV59962117; called by muse, mutect2, varscan2
- CDCA7L | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs750543368, COSV100651164; called by muse, mutect2, varscan2
- CDKN2A | c.230del p.T77Ifs*69 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as COSV100447090, COSV58727079; called by mutect2, pindel*, varscan2
- CEMIP2 | c.749C>T p.S250L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100987444; called by muse, mutect2, varscan2
- CFAP46 | c.6130G>A p.E2044K | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); catalogued as COSV54155444, COSV99585233; called by muse, mutect2, varscan2
- CHN1 | c.681G>T p.W227C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99789315; called by muse, mutect2, varscan2
- COL9A3 | c.1161G>A p.A387= | Splice Region (SNP) | VAF 4/10 reads (40%) | catalogued as rs770709536, COSV100673500; called by muse, varscan2
- CORO2A | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as COSV59663848, COSV59664854; called by muse, mutect2, varscan2
- CPAMD8 | c.4147C>T p.R1383C (on ENST00000651564; = p.R1336C on NM_015692.5) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as rs752813564, COSV101488544; called by muse, mutect2, varscan2
- CR1 | c.5528C>G p.S1843C | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.919); catalogued as COSV100887871; called by muse, mutect2, varscan2
- CSPG4 | c.3146C>T p.S1049L | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs531178999, COSV100413910; called by muse, mutect2, varscan2
- CTCFL | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 32/84 reads (38%) | catalogued as COSV99713055; called by muse, mutect2, varscan2
- CYP1B1 | c.1390dup p.S464Ffs*14 | Frame Shift Ins (INS) | VAF 19/79 reads (24%) | catalogued as rs777515179; called by mutect2, pindel, varscan2
- DMXL2 | c.8994G>A p.M2998I | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV99196706; called by muse, mutect2, varscan2
- DNAH9 | c.11993C>A p.P3998H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.412); catalogued as COSV99305868; called by muse, mutect2, varscan2
- DND1 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs1167644251, COSV100298146; called by muse, mutect2, varscan2
- DSG4 | c.1318G>C p.D440H | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100356143; called by muse, mutect2, varscan2
- DYNC2H1 | c.10489G>A p.E3497K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV100519106; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777283446, COSV62571797; called by muse, mutect2, varscan2
- EEF1B2 | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99261208; called by muse, mutect2, varscan2
- ENAM | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as COSV68535710; called by muse, mutect2, varscan2
- EPG5 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.125); catalogued as COSV99957697; called by muse, mutect2, varscan2
- EPHA5 | c.1912C>A p.H638N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.22); catalogued as COSV56630592; called by muse, mutect2, varscan2
- FAM171B | c.675G>C p.L225F | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as COSV100488456, COSV100488805, COSV59001118; called by muse, mutect2, varscan2
- FAM47A | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374052739, COSV60496340; called by muse, mutect2, varscan2
- FARSB | c.1636G>A p.G546R | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs778432967, COSV99918505; called by muse, mutect2, varscan2
- FAT1 | c.5515G>T p.E1839* | Nonsense Mutation (SNP) | VAF 13/25 reads (52%) | catalogued as COSV71675362; called by muse, mutect2, varscan2
- FBXW2 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs368572383; called by muse, mutect2, varscan2
- GABPB1 | c.722C>A p.S241* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as COSV99589939; called by muse, mutect2, varscan2
- GORAB | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100883772; called by muse, mutect2, varscan2
- H2BC5 | c.222C>G p.I74M | Missense Mutation (SNP) | VAF 85/265 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.87); catalogued as rs1358692800, COSV56800766, COSV56803159, COSV99175306; called by muse, mutect2, varscan2
- HECTD4 | c.2767C>T p.L923F | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.9); catalogued as COSV100296139; called by muse, mutect2, varscan2
- IGHV2-5 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.495); catalogued as rs782632670; called by muse, mutect2, varscan2
- IRAK3 | c.601C>A p.Q201K | Missense Mutation (SNP) | VAF 101/345 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.301); catalogued as rs953465508, COSV99706310; called by muse, mutect2, varscan2
- KEAP1 | c.1557C>G p.I519M | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99408036; called by muse, mutect2, varscan2
- KIF13A | c.3944C>T p.T1315I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV99436957; called by muse, mutect2, varscan2
- KIF18A | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV99588920; called by muse, mutect2, varscan2
- KLHL6 | c.80C>G p.S27C | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.19); catalogued as COSV100384857; called by muse, mutect2, varscan2
- KLK3 | c.193C>A p.H65N | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100386041; called by muse, mutect2, varscan2
- KNL1 | c.4952A>G p.K1651R (on ENST00000346991 / NM_170589.5; = p.K1625R on NM_144508.5) | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.098); catalogued as COSV100706752; called by muse, mutect2, varscan2
- L3MBTL2 | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.482); catalogued as COSV99346004; called by muse, mutect2, varscan2
- LRP2 | c.12787G>C p.D4263H | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99789481; called by muse, mutect2, varscan2
- MAP3K9 | c.918G>T p.K306N | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101173703; called by muse, mutect2, varscan2
- MAPKBP1 | c.4523G>A p.R1508Q (on ENST00000456763 / NM_001128608.2; = p.R1502Q on NM_014994.3) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as rs751962626, COSV99529865; called by muse, mutect2, varscan2
- MFAP1 | c.480A>C p.K160N | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV99979996; called by muse, mutect2, varscan2
- MGA | c.1496C>A p.S499Y | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99580697; called by muse, mutect2, varscan2
- MKI67 | c.6022G>C p.V2008L | Missense Mutation (SNP) | VAF 88/307 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100896812; called by muse, mutect2, varscan2
- MRPL22 | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as rs1258653015, COSV54558804; called by muse, mutect2, varscan2
- MSL2 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99387733; called by muse, mutect2, varscan2
- MYCBP2 | c.11618G>T p.G3873V (on ENST00000357337; = p.G3911V on NM_015057.5) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100631030; called by muse, mutect2, varscan2
- MYO16 | c.1723A>G p.T575A | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV99194196; called by muse, mutect2, varscan2
- NOP2 | c.791C>T p.S264F (on ENST00000322166 / NM_001258308.2; = p.S260F on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs1483988669, COSV100444587; called by muse, varscan2
- NPFFR2 | c.1556G>A p.S519N | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV100441005; called by muse, mutect2, varscan2
- OLFML2B | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs770109507, COSV99668671; called by muse, mutect2, varscan2
- OR10H1 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.41); catalogued as COSV100612453; called by muse, mutect2, varscan2
- OR8B12 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.902); catalogued as rs369152224, COSV60912115; called by muse, mutect2, varscan2
- PIGV | c.921C>G p.I307M | Missense Mutation (SNP) | VAF 87/318 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99315071; called by muse, mutect2, varscan2
- PLEKHH3 | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV99512157; called by muse, mutect2, varscan2
- POGZ | c.2950G>T p.A984S | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99305113; called by muse, mutect2, varscan2
- PRPF8 | c.2956G>C p.E986Q | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as COSV100517695; called by muse, mutect2, varscan2
- PSTPIP1 | c.744C>G p.L248= | Splice Region (SNP) | VAF 9/68 reads (13%) | catalogued as COSV99143796; called by muse, mutect2, varscan2
- RBFOX1 | c.208C>A p.Q70K | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.83); catalogued as COSV100302538; called by muse, mutect2, varscan2
- SH2D5 | c.1252G>A p.E418K (on ENST00000444387 / NM_001103161.2; = p.E334K on NM_001103160.2) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.027); catalogued as COSV99929406; called by muse, mutect2
- SLC12A1 | c.1031G>A p.G344E | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100372442; called by muse, mutect2, varscan2
- SLC22A12 | c.1599-2A>T p.X533_splice | Splice Site (SNP) | VAF 5/25 reads (20%) | catalogued as COSV99635025; called by muse, mutect2, varscan2
- SLC2A2 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV58588886; called by muse, mutect2, varscan2
- SLC4A1 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs121912756, CM004493, COSV99070879, COSV99293516; ClinVar: affects; called by muse, mutect2, varscan2
- SLC4A1 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99293518; called by muse, mutect2, varscan2
- SLC9A3R2 | c.972G>C p.Q324H (on ENST00000424542 / NM_001130012.3; = p.Q313H on NM_004785.6) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs1237268733, COSV99526420; called by muse, varscan2
- SMYD1 | c.36C>G p.F12L | Missense Mutation (SNP) | VAF 83/340 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV101352472; called by muse, mutect2, varscan2
- SNX10 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 84/242 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs781633301, COSV100640115; called by muse, mutect2, varscan2
- SRF | c.972G>C p.K324N | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs778816086, COSV99541895; called by muse, mutect2, varscan2
- TAS2R8 | c.446C>A p.A149E | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.266); catalogued as COSV99553882; called by muse, mutect2, varscan2
- TBC1D4 | c.1370C>G p.P457R | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66487991, COSV66489513; called by muse, mutect2, varscan2
- TG | c.4268G>A p.R1423H | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs146594373; called by muse, mutect2, varscan2
- THOC6 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as rs960258274, COSV50187951; called by muse, mutect2, varscan2
- TIMD4 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.084); catalogued as rs375659101; called by muse, mutect2, varscan2
- TMF1 | c.112T>A p.W38R | Missense Mutation (SNP) | VAF 53/90 reads (59%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV100734732; called by muse, mutect2, varscan2
- TP53 | c.1043T>C p.L348S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52736234, COSV53072454, COSV99425698; called by muse, mutect2, varscan2
- TP53 | c.778del p.S260Pfs*85 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as COSV52950491, COSV53107447, COSV53210439; called by mutect2, pindel*, varscan2
- TRPM3 | c.1291C>T p.R431W (on ENST00000357533 / NM_001366142.2; = p.R276W on NM_020952.6) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs761235261, COSV62579679; called by muse, mutect2, varscan2
- TTC16 | c.200G>C p.R67T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.412); catalogued as COSV100076966; called by muse, mutect2, varscan2
- TYW1 | c.391G>T p.V131F | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV100658902; called by muse, mutect2, varscan2
- UAP1 | c.1051C>T p.H351Y | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV99617875; called by muse, mutect2, varscan2
- URI1 | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100369111; called by muse, mutect2, varscan2
- USP11 | c.2374G>A p.E792K (on ENST00000218348; = p.E749K on NM_001371072.1) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99511054; called by muse, mutect2, varscan2
- WWC2 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.383); catalogued as COSV100968428; called by muse, mutect2, varscan2
- ZNF280A | c.1385C>G p.T462R | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100131043, COSV100131133; called by muse, mutect2, varscan2
- ZNF586 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.222); catalogued as COSV101197707; called by muse, mutect2, varscan2
- ZNF615 | c.1159C>G p.L387V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100943884; called by muse, mutect2, varscan2
- ZNF684 | c.554A>C p.K185T | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV101016078; called by muse, mutect2, varscan2
- ZNF804B | c.162del p.Y56Tfs*30 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | catalogued as COSV100306077, COSV60817945; called by mutect2, pindel, varscan2
- AGRN | c.2376_2385del p.C793Tfs*67 | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | called by mutect2, pindel, varscan2
- KNL1 | c.3248dup p.L1084Sfs*12 (on ENST00000346991 / NM_170589.5; = p.L1058Sfs*12 on NM_144508.5) | Frame Shift Ins (INS) | VAF 11/70 reads (16%) | called by mutect2, pindel, varscan2
- RALGPS2 | c.57+2dup p.X19_splice | Splice Site (INS) | VAF 8/31 reads (26%) | called by mutect2, pindel, varscan2
- RLF | c.568_570del p.L190del | In Frame Del (DEL) | VAF 14/44 reads (32%) | called by pindel, varscan2
- SF3B6 | c.68_69dup p.R24* | Frame Shift Ins (INS) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- ZFYVE26 | c.1977del p.P660Lfs*9 | Frame Shift Del (DEL) | VAF 26/92 reads (28%) | called by mutect2, pindel, varscan2
- ANKRD30A | c.474G>T p.L158= (on ENST00000611781; = p.L102= on NM_052997.2) | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV64611540; called by muse, mutect2, varscan2
- BAG3 | c.117C>T p.F39= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV100958263; called by muse, mutect2, varscan2
- CANX | c.843C>T p.D281= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as rs1345910313, COSV99910565; called by muse, mutect2, varscan2
- CD163 | c.495G>A p.G165= | Silent (SNP) | VAF 55/216 reads (25%) | catalogued as rs766179361, COSV63129001; called by muse, mutect2, varscan2
- CDK18 | c.735C>T p.L245= (on ENST00000506784 / NM_212503.3; = p.L215= on NM_002596.4) | Silent (SNP) | VAF 42/142 reads (30%) | catalogued as COSV100774070, COSV63726917; called by muse, mutect2, varscan2
- CYB5R2 | c.57G>T p.P19= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV100207521, COSV55087363; called by muse, mutect2, varscan2
- CYFIP2 | c.2412G>A p.L804= (on ENST00000616178 / NM_001291722.2; = p.L779= on NM_014376.4) | Silent (SNP) | VAF 82/323 reads (25%) | catalogued as rs1418922914, COSV100557422; called by muse, mutect2, varscan2
- DAXX | c.1791C>T p.F597= | Silent (SNP) | VAF 43/120 reads (36%) | catalogued as COSV99802393; called by muse, mutect2, varscan2
- EGR2 | c.1377C>T p.S459= | Silent (SNP) | VAF 43/145 reads (30%) | catalogued as COSV54347040, COSV99654219; called by muse, mutect2, varscan2
- GDF10 | c.30G>A p.P10= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs782790604; called by muse, mutect2, varscan2
- GIMAP2 | c.387G>A p.V129= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs1262345165, COSV99785436; called by muse, mutect2, varscan2
- GPR12 | c.720G>A p.T240= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs534837095, COSV101198001; called by muse, mutect2, varscan2
- GRK5 | c.111T>A p.P37= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV101230484; called by muse, mutect2, varscan2
- H3C4 | c.174G>A p.S58= | Silent (SNP) | VAF 54/161 reads (34%) | catalogued as COSV100587226, COSV61911782; called by muse, mutect2, varscan2
- H4C5 | c.273G>A p.L91= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs143252055; called by muse, mutect2, varscan2
- ITGA5 | c.1629A>G p.T543= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as COSV99516774; called by muse, mutect2, varscan2
- JMY | c.2382A>G p.E794= | Silent (SNP) | VAF 41/133 reads (31%) | catalogued as COSV101268072; called by muse, mutect2, varscan2
- LRIG3 | c.882C>T p.L294= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV100292740; called by muse, mutect2, varscan2
- LRP1 | c.1548G>C p.G516= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV99676544; called by muse, mutect2, varscan2
- LRRN4 | c.850C>T p.L284= | Silent (SNP) | VAF 41/141 reads (29%) | catalogued as COSV101125491; called by muse, mutect2, varscan2
- MRC2 | c.3315C>T p.F1105= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100316478; called by muse, mutect2, varscan2
- MRPL53 | c.336C>T p.R112= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as COSV99252183; called by muse, mutect2, varscan2
- MSH5 | c.2235C>T p.C745= | Silent (SNP) | VAF 52/147 reads (35%) | catalogued as rs1174649021, COSV100991908; called by muse, mutect2, varscan2
- NEK3 | c.123C>T p.F41= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs1468840391, COSV99317734; called by muse, mutect2
- NOP2 | c.748C>T p.L250= (on ENST00000322166 / NM_001258308.2; = p.L246= on NM_006170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100445046; called by muse, varscan2
- NPAS1 | c.1374C>A p.T458= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV99451421; called by muse, mutect2, varscan2
- PAPOLB | c.1740G>A p.V580= | Silent (SNP) | VAF 23/112 reads (21%) | catalogued as COSV101271528; called by muse, mutect2, varscan2
- POMGNT1 | c.1590C>G p.L530= | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as COSV100915712; called by muse, mutect2, varscan2
- RGS7 | c.681G>A p.R227= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs776776253, COSV58541971; called by muse, mutect2, varscan2
- SLC22A7 | c.969C>T p.A323= (on ENST00000372585 / NM_153320.2; = p.A321= on NM_006672.3) | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs1362304680, COSV51486311, COSV99240368; called by muse, mutect2, varscan2
- SLC39A11 | c.798G>A p.G266= (on ENST00000542342 / NM_001159770.2; = p.G259= on NM_139177.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99723466; called by muse, mutect2, varscan2
- SRF | c.789G>A p.L263= | Silent (SNP) | VAF 55/187 reads (29%) | catalogued as COSV99541894; called by muse, mutect2, varscan2
- TECTA | c.288C>T p.V96= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs750330420, COSV99880639; called by muse, mutect2, varscan2
- UNC5B | c.180G>A p.V60= | Silent (SNP) | VAF 45/136 reads (33%) | catalogued as COSV100100570; called by muse, mutect2, varscan2
- VPS25 | c.15C>T p.F5= | Silent (SNP) | VAF 52/171 reads (30%) | catalogued as rs1377761541, COSV99519513; called by muse, mutect2, varscan2
- ZNF521 | c.3174C>A p.G1058= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV100832806; called by muse, mutect2, varscan2
- ANKRD13D | c.*1446_*1452del | 3'UTR (DEL) | VAF 20/101 reads (20%) | called by mutect2, pindel, varscan2
- TFE3 | c.*123_*125del | 3'UTR (DEL) | VAF 17/27 reads (63%) | called by pindel, varscan2
- ZNF587 | c.-2C>G | 5'UTR (SNP) | VAF 19/64 reads (30%) | catalogued as COSV100299599; called by muse, mutect2, varscan2
